Somatic mutation profile of tumor specimen TCGA-K1-A6RT-01A (aliquot TCGA-K1-A6RT-01A-32D-A33E-09) from TCGA case TCGA-K1-A6RT, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 48.6 years (17,739 days).
Specimen TCGA-K1-A6RT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47720a02-74c1-45ba-acbf-177402e04320.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K1-A6RT-10A (Blood Derived Normal), aliquot TCGA-K1-A6RT-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/681b3cea-9683-4a14-ad9d-b7eceea7f7d2

The open-access MAF lists 46 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 12, Intron 2, Splice Site 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ALPI | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.099); catalogued as rs767790837, COSV99785783; called by muse, mutect2
- CCDC190 | c.402G>T p.M134I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100905815; called by muse, mutect2
- CHSY1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1320280755, COSV54251858, COSV99574264; ClinVar: uncertain significance; called by muse, mutect2
- CX3CL1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs558560542, COSV99136284; called by muse, mutect2
- ELOA | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs1213533133, COSV69309466; called by muse, mutect2
- FBXO11 | c.482A>G p.D161G (on ENST00000403359 / NM_001190274.2; = p.D77G on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100319282; called by muse, mutect2
- GPR143 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1309522047, COSV101102189; called by mutect2, varscan2
- ITPR1 | c.6839C>T p.S2280L (on ENST00000354582; = p.S2225L on NM_002222.7) | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as rs1379792070, COSV56981900; called by muse, mutect2
- LAMA2 | c.4025A>G p.K1342R | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as COSV101370293; called by muse, mutect2, varscan2
- LCN8 | c.307A>T p.I103F (on ENST00000612714 / NM_001345934.1; = p.I80F on NM_178469.3) | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV100293366; called by muse, mutect2
- LRRK2 | c.2288A>G p.N763S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100109702; called by muse, mutect2
- NCAN | c.2785C>G p.P929A | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV53060075, COSV99386929; called by muse, mutect2
- NOC4L | c.536A>G p.D179G | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100223004; called by muse, mutect2
- PCDH1 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99745856; called by muse, mutect2, varscan2
- PI4KA | c.5663C>T p.A1888V | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99745356; called by muse, mutect2
- POLR3H | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV100519898; called by muse, mutect2
- PTPRU | c.3677A>T p.D1226V | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100112262; called by muse, mutect2
- PTRH1 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs1446283660, COSV58851848; called by muse, mutect2
- RTN1 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1316938867, COSV50718696, COSV50732818; called by muse, mutect2
- SCAP | c.410+1G>A p.X137_splice | Splice Site (SNP) | VAF 11/117 reads (9%) | catalogued as COSV99652576; called by muse, mutect2
- SCN2A | c.2351C>T p.T784M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs758872788, COSV51830904; called by muse, mutect2, varscan2
- SEC14L4 | c.1007T>C p.V336A | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV99742826; called by muse, mutect2
- SGTA | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs1390800497, COSV99682515; called by muse, mutect2
- STOML2 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as rs1475635497, COSV99956554; called by muse, mutect2, varscan2
- STRA8 | c.535G>A p.A179T (on ENST00000275764; = p.A157T on NM_182489.2) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.089); catalogued as COSV51960937; called by muse, mutect2
- THADA | c.5582G>A p.R1861H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs765254477, COSV99143648; called by muse, mutect2, varscan2
- WDR55 | c.680G>A p.C227Y | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as rs927556981, COSV100297957; called by muse, mutect2
- JAG1 | c.3301A>G p.S1101G | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- MARCHF9 | c.605T>C p.L202P | Missense Mutation (SNP) | VAF 3/65 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PARP11 | c.778dup p.I260Nfs*13 | Frame Shift Ins (INS) | VAF 5/46 reads (11%) | called by mutect2, pindel
- APPL2 | c.684C>T p.S228= | Silent (SNP) | VAF 18/216 reads (8%) | catalogued as rs577280673, COSV51589598; called by muse, mutect2
- CNN1 | c.417C>T p.N139= | Silent (SNP) | VAF 22/233 reads (9%) | catalogued as rs746360577, COSV99372283; called by muse, mutect2
- GRK3 | c.594A>G p.G198= | Silent (SNP) | VAF 8/228 reads (4%) | catalogued as COSV100151322; called by muse, mutect2
- MRC1 | c.2481T>C p.F827= | Silent (SNP) | VAF 12/364 reads (3%) | called by muse, mutect2
- MUC5B | c.4158C>T p.P1386= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as rs555563575, COSV101500099, COSV71591879, COSV71594423; called by muse, mutect2
- PCDHB8 | c.960C>T p.I320= | Silent (SNP) | VAF 14/372 reads (4%) | catalogued as COSV50812355; called by muse, mutect2
- PEG3 | c.2220T>A p.P740= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV99688200; called by muse, mutect2
- RETREG2 | c.1539A>G p.T513= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99811443; called by muse, mutect2
- UHRF1 | c.963C>T p.C321= (on ENST00000612630 / NM_001290050.1; = p.C334= on NM_013282.4) | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as rs778664373, COSV99503408; called by muse, mutect2
- VANGL2 | c.1329G>A p.A443= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs146767141; called by muse, mutect2
- ZC3H18 | c.117C>T p.D39= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs770435213, COSV56324730; called by muse, mutect2, varscan2
- ZMYM4 | c.2256T>C p.C752= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV100109975; called by muse, mutect2
- AGBL5 | c.2089+14G>T | Intron (SNP) | VAF 13/106 reads (12%) | catalogued as COSV100548998; called by muse, mutect2, varscan2
- AL590867.2 | n.91G>A | RNA (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2, varscan2
- SH3GLB1 | c.570+4025G>C | Intron (SNP) | VAF 4/48 reads (8%) | catalogued as rs899410624, COSV100990751; called by muse, mutect2
